Somatic mutation profile of tumor specimen TCGA-L5-A88S-01A (aliquot TCGA-L5-A88S-01A-11D-A36J-09) from TCGA case TCGA-L5-A88S, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IB; Tumor grade: GX; Age at diagnosis: 84.7 years (30,954 days).
Specimen TCGA-L5-A88S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80bc2aab-d599-48ac-a193-84c7a8fa483d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A88S-11A (Solid Tissue Normal), aliquot TCGA-L5-A88S-11A-21D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8802982e-a4ba-4a9e-9a34-4254f61bf81a

The open-access MAF lists 94 somatic variants for this specimen: 71 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 20, RNA 3, Frame Shift Del 2, Nonsense Mutation 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 40/88 reads (45%) | hotspot (GDC flag); catalogued as rs764735889, COSV52685086, COSV53209009; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACVR1B | c.1358G>A p.R453H | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57775684; called by muse, mutect2, varscan2
- C1R | c.638C>T p.T213M (on ENST00000536053 / NM_001354346.2; = p.T199M on NM_001733.7) | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1433372595; called by muse, mutect2
- CLVS2 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs766143997, COSV104390204; called by muse, mutect2, varscan2
- CRNKL1 | c.2045A>G p.Y682C | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as rs1212913079; called by muse, mutect2, varscan2
- CTU2 | c.563T>C p.L188P | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.564); catalogued as COSV99965902; called by muse, mutect2, varscan2
- EPHA5 | c.3097G>A p.G1033R | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.106); catalogued as rs139793674; called by muse, mutect2, varscan2
- FAT3 | c.5079C>G p.I1693M | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV99965533; called by muse, mutect2, varscan2
- FGF23 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1459493249, COSV52975044; called by muse, mutect2, varscan2
- FNDC1 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs780310956; called by muse, mutect2, varscan2
- FUT9 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.427); catalogued as rs763326668, COSV56150369; called by muse, mutect2, varscan2
- HBE1 | c.108C>A p.Y36* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as rs1274644435; called by muse, mutect2, varscan2
- HBP1 | c.250C>A p.Q84K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as rs949778025; called by muse, mutect2, varscan2
- HRNR | c.5650T>A p.Y1884N | Missense Mutation (SNP) | VAF 30/762 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100913845, COSV64258230; called by muse, mutect2
- IL1RAPL2 | c.2052T>G p.D684E | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.3); catalogued as COSV100782317; called by muse, mutect2, varscan2
- KMT5B | c.1294A>G p.I432V | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1236378447; called by muse, mutect2
- LILRA6 | c.1283C>T p.P428L | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1446713792; called by muse, mutect2, varscan2
- MS4A10 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.138); catalogued as rs1383022836, COSV57633047; called by muse, mutect2, varscan2
- MYO15A | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs990963529, COSV52764171, COSV52765249; called by muse, mutect2, varscan2
- NCDN | c.1516G>A p.D506N | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs768006525; called by muse, mutect2, varscan2
- NDST4 | c.550C>A p.L184I | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.042); catalogued as rs564044682, COSV52131759, COSV52141204, COSV99995081; called by muse, mutect2, varscan2
- NSMCE1 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as rs753831018, COSV53729917; called by muse, mutect2, varscan2
- NUAK1 | c.1822C>T p.L608F | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99777352; called by muse, mutect2, varscan2
- OR2T3 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs757364328; called by muse, mutect2, varscan2
- PCDHB12 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as COSV53396364, COSV53399976; called by muse, mutect2, varscan2
- PKIA | c.221C>A p.S74Y | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV61916693; called by muse, mutect2, varscan2
- RANBP2 | c.1340T>C p.L447S | Missense Mutation (SNP) | VAF 87/419 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.134); catalogued as rs539147212; called by muse, mutect2, varscan2
- SFXN2 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376492604; called by muse, mutect2, varscan2
- ZNF804B | c.1108C>A p.P370T | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV60827323; called by muse, mutect2, varscan2
- ACVR1C | c.1225+2T>C p.X409_splice | Splice Site (SNP) | VAF 21/129 reads (16%) | called by muse, mutect2, varscan2
- AFF2 | c.2887G>T p.A963S | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.026); called by muse, mutect2
- AKAP9 | c.8900T>A p.I2967K (on ENST00000359028; = p.I2943K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ASPM | c.2920T>G p.C974G | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CCNI2 | c.1079G>A p.C360Y | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.96); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- COBLL1 | c.1858A>G p.I620V (on ENST00000392717; = p.I582V on NM_014900.5) | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DDX54 | c.393G>C p.L131F | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- DIDO1 | c.572A>T p.K191M | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- EGF | c.2102A>G p.D701G | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- FAT1 | c.1886del p.S629Cfs*2 | Frame Shift Del (DEL) | VAF 17/71 reads (24%) | called by mutect2, pindel, varscan2
- KAT6A | c.980T>C p.I327T | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KDM1A | c.2373G>T p.Q791H | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.269); called by muse, mutect2
- KIF11 | c.966T>A p.D322E | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF16B | c.1243G>A p.V415I | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- KREMEN1 | c.664T>G p.S222A (on ENST00000407188; = p.S224A on NM_032045.5) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LAMB1 | c.4592T>C p.M1531T | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- LIN9 | c.559C>T p.P187S (on ENST00000366808 / NM_001270410.2; = p.P132S on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRP5 | c.1451T>C p.I484T | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- LRRIQ1 | c.4541G>T p.R1514I | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- MPZL1 | c.448A>T p.I150F | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- MYH1 | c.1184C>G p.S395C | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- MYH2 | c.5309T>A p.M1770K | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- NOTCH2 | c.938G>A p.G313D | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OSBPL9 | c.2039A>C p.D680A | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PCDHA10 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- PDZD2 | c.1915G>C p.D639H | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- PLXNA2 | c.2739G>T p.Q913H | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- POC5 | c.234_235dup p.E79Vfs*3 (on ENST00000428202 / NM_001099271.2; = p.E54Vfs*3 on NM_152408.2) | Frame Shift Ins (INS) | VAF 10/110 reads (9%) | called by mutect2, pindel
- PSD | c.1256C>G p.S419C | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- SGK3 | c.244T>A p.F82I | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- SHANK2 | c.3799C>A p.Q1267K | Missense Mutation (SNP) | VAF 16/209 reads (8%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.479); called by muse, mutect2
- SLC7A14 | c.1548G>A p.M516I | Missense Mutation (SNP) | VAF 20/362 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2
- SLX4IP | c.298A>G p.R100G | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPIRE2 | c.1184A>G p.D395G | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TBC1D4 | c.129del p.S44Rfs*39 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | called by mutect2, pindel, varscan2
- THSD4 | c.2879A>G p.E960G | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TNXB | c.8569G>T p.D2857Y (on ENST00000647633; = p.D2610Y on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TOPBP1 | c.4509A>T p.L1503F | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRAV9-1 | c.161G>T p.W54L | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ULK1 | c.3029C>T p.A1010V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZC3H12A | c.1276G>C p.D426H | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.117); called by muse, mutect2
- ZNF384 | c.1198G>C p.D400H (on ENST00000361959; = p.D339H on NM_133476.5) | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ALPK2 | c.4890T>C p.P1630= | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as rs1197906924; called by muse, mutect2, varscan2
- CACNA1H | c.6711C>A p.G2237= | Silent (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- CBLIF | c.750G>A p.T250= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as rs377432418, COSV99950858; ClinVar: benign; called by muse, mutect2, varscan2
- CD93 | c.660G>A p.A220= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as rs1169117421, COSV55665905; called by muse, mutect2, varscan2
- DBI | c.114C>A p.G38= (on ENST00000355857 / NM_001079862.3; = p.G55= on NM_020548.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV58346722; called by muse, mutect2, varscan2
- DCDC1 | c.5163C>T p.D1721= (on ENST00000597505 / NM_001367979.1; = p.D828= on NM_020869.3) | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs532651593, COSV58004266; called by muse, mutect2, varscan2
- HCFC1R1 | c.204C>T p.F68= | Silent (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- IGFN1 | c.3663G>A p.P1221= (on ENST00000295591 / NM_001367841.1; = p.P3678= on NM_001164586.2) | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs749503568; called by muse, mutect2, varscan2
- IL6ST | c.831A>T p.T277= | Silent (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2, varscan2
- IQUB | c.411T>C p.L137= | Silent (SNP) | VAF 38/124 reads (31%) | called by muse, mutect2, varscan2
- KDM4B | c.2652C>T p.H884= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs1168773951, COSV50216175; called by muse, mutect2, varscan2
- KMT2B | c.4044C>T p.N1348= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs761407686; called by muse, mutect2, varscan2
- LIG1 | c.1980C>T p.F660= | Silent (SNP) | VAF 36/69 reads (52%) | catalogued as rs774839059, COSV54389375; called by muse, mutect2, varscan2
- OR2AG2 | c.99C>A p.I33= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV58455195; called by muse, mutect2, varscan2
- PCDH12 | c.1803G>A p.A601= | Silent (SNP) | VAF 30/142 reads (21%) | catalogued as rs769053658; called by muse, mutect2, varscan2
- PRICKLE3 | c.1155C>T p.G385= | Silent (SNP) | VAF 29/46 reads (63%) | called by muse, mutect2, varscan2
- RBMX2 | c.42T>C p.N14= | Silent (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- SEMA3A | c.1305C>G p.V435= | Silent (SNP) | VAF 38/115 reads (33%) | catalogued as COSV54890859; called by muse, mutect2, varscan2
- SFXN5 | c.612G>A p.P204= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs148672407; called by muse, mutect2, varscan2
- TEP1 | c.6147A>G p.E2049= | Silent (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- AL590867.2 | n.264G>A | RNA (SNP) | VAF 33/143 reads (23%) | called by muse, mutect2, varscan2
- LINC00922 | n.902C>T | RNA (SNP) | VAF 10/31 reads (32%) | catalogued as rs375252980; called by muse, mutect2, varscan2
- MIR409 | n.43C>T | RNA (SNP) | VAF 12/53 reads (23%) | catalogued as rs773414152; called by muse, mutect2, varscan2
